Somatic mutation profile of tumor specimen TCGA-FR-A3R1-01A (aliquot TCGA-FR-A3R1-01A-11D-A23B-08) from TCGA case TCGA-FR-A3R1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 69.2 years (25,271 days).
Specimen TCGA-FR-A3R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 273bc057-fd4f-4f67-9dfe-78d5c7e4be38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A3R1-10B (Blood Derived Normal), aliquot TCGA-FR-A3R1-10B-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d63e694-0052-48ea-9c78-41a9a9716b68

The open-access MAF lists 515 somatic variants for this specimen: 319 protein-altering or splice-affecting, 183 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 287, Silent 183, Nonsense Mutation 20, Intron 8, Splice Site 3, RNA 3, Splice Region 3, Frame Shift Del 2, Frame Shift Ins 2, 3'Flank 2, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 45/116 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by muse, mutect2, varscan2
- NCR1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 78/206 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV52555848; called by muse, mutect2, varscan2
- NF1 | c.3208C>T p.Q1070* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as rs786202023, CD1415159, CM143363, COSV62209207; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 128/194 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, varscan2
- SCN1A | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 71/200 reads (36%) | catalogued as rs794726799, CM067015, COSV57667265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYT13 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 104/216 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs868559206, COSV50072436, COSV50073637; called by muse, mutect2, varscan2
- ABCE1 | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as rs1203761174, COSV56849056; called by muse, mutect2, varscan2
- ACD | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs868651125, COSV54666888; called by muse, mutect2, varscan2
- ACSM1 | c.944G>T p.W315L | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54639160, COSV54640038; called by muse, mutect2, varscan2
- ACSM2A | c.1720G>A p.A574T (on ENST00000219054; = p.A495T on NM_001308169.2) | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV54589690; called by muse, mutect2, varscan2
- ACVR1C | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 71/213 reads (33%) | catalogued as rs775081249, COSV54643616; called by muse, mutect2, varscan2
- ADAM28 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763653445, COSV56105266; called by muse, mutect2, varscan2
- ADAMTS12 | c.4177G>C p.D1393H | Missense Mutation (SNP) | VAF 109/298 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100710675, COSV100711757, COSV61279065; called by muse, mutect2, varscan2
- ADCY10 | c.4243C>T p.H1415Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63244818; called by muse, mutect2, varscan2
- ADCY8 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53926716; called by muse, mutect2, varscan2
- ADGRG5 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200838029, COSV61084547; called by muse, mutect2, varscan2
- ADGRL4 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as rs771201747, COSV66061203; called by muse, mutect2, varscan2
- AK5 | c.557T>C p.I186T (on ENST00000354567 / NM_174858.3; = p.I160T on NM_012093.4) | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58357039; called by muse, mutect2
- ALDH8A1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV55644271; called by muse, mutect2, varscan2
- ALK | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV66589067; called by muse, mutect2, varscan2
- ANK3 | c.2617G>A p.E873K (on ENST00000280772 / NM_001320874.2; = p.E7K on NM_001149.3) | Missense Mutation (SNP) | VAF 96/305 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV55080838; called by muse, mutect2, varscan2
- ANKMY1 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs767488742, COSV56040738; called by muse, mutect2, varscan2
- ANKRD6 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV60236849; called by muse, mutect2, varscan2
- ARAP1 | c.824G>A p.G275E (on ENST00000393609 / NM_001040118.2; = p.G30E on NM_015242.4) | Missense Mutation (SNP) | VAF 154/430 reads (36%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); catalogued as COSV61994925; called by muse, mutect2, varscan2
- ASPM | c.9134G>A p.G3045E | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as rs771829922, COSV99660905; called by muse, mutect2, varscan2
- ASPM | c.9133G>A p.G3045R | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.261); catalogued as COSV99660906; called by muse, mutect2, varscan2
- ATP23 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV55687270; called by muse, mutect2, varscan2
- ATP7A | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 158/230 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV58453640; called by muse, mutect2, varscan2
- BAIAP3 | c.2842C>T p.H948Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV50105423, COSV99136346; called by muse, mutect2, varscan2
- BEND4 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV101549788; called by muse, mutect2, varscan2
- BLM | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs139282091, COSV99049972; ClinVar: uncertain significance / not provided; called by muse, varscan2
- BMP2K | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs748826365, COSV58599227; called by muse, mutect2, varscan2
- C1QTNF9 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100129988; called by muse, mutect2, varscan2
- C1QTNF9 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100129990; called by muse, mutect2, varscan2
- C3 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55573205; called by muse, mutect2, varscan2
- C5 | c.3277G>A p.V1093I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs371131390; called by muse, mutect2, varscan2
- C7 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57479866; called by muse, mutect2, varscan2
- CACNA1S | c.2249C>G p.P750R | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62943530; called by muse, mutect2, varscan2
- CCDC68 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100491961; called by muse, mutect2, varscan2
- CCDC68 | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as rs761969346, COSV61604542; called by muse, mutect2, varscan2
- CCNY | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs199767699; called by muse, mutect2, varscan2
- CD163 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 113/336 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63137027; called by muse, mutect2, varscan2
- CD2AP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 153/701 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV63762976; called by muse, mutect2, varscan2
- CD300E | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV60790788, COSV60791705; called by muse, mutect2
- CD300LG | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as COSV53225754; called by muse, mutect2, varscan2
- CD33 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.496); catalogued as COSV99220701; called by muse, mutect2, varscan2
- CDC42EP4 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59964222; called by muse, mutect2, varscan2
- CDCP1 | c.827G>A p.R276K | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV56108021; called by muse, mutect2, varscan2
- CFAP61 | c.3109G>A p.G1037R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.341); catalogued as COSV55617962; called by muse, mutect2, varscan2
- CFHR2 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV66382218; called by muse, mutect2, varscan2
- CFTR | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1163971376, COSV50097722; called by muse, mutect2, varscan2
- CHID1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs757215367, COSV60259928; called by muse, mutect2, varscan2
- CLCNKB | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV65160209; called by muse, mutect2, varscan2
- CLUH | c.1696C>A p.L566M (on ENST00000435359; = p.L604M on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs61297645, COSV101425856; called by muse, varscan2
- CNR1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.367); catalogued as COSV62988046, COSV62989058; called by muse, mutect2, varscan2
- COL13A1 | c.1824C>A p.D608E (on ENST00000398978 / NM_001130103.2; = p.D536E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs768058364, COSV100637687; called by muse, mutect2, varscan2
- COL13A1 | c.1825C>T p.R609C (on ENST00000398978 / NM_001130103.2; = p.R537C on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776165085, COSV100637689; called by muse, mutect2, varscan2
- COL19A1 | c.2975G>A p.G992E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1208878749, COSV59587656; called by muse, mutect2, varscan2
- COL3A1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.738); catalogued as rs1244182383, COSV58594030; called by muse, mutect2, varscan2
- COL4A4 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306418; called by muse, mutect2, varscan2
- COL4A4 | c.1660G>T p.G554W | Missense Mutation (SNP) | VAF 85/292 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307461; called by muse, mutect2, varscan2
- COL5A1 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199703883, COSV65674536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A3 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53418882; called by muse, mutect2, varscan2
- COL8A1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs766271324, COSV53742422; called by muse, mutect2, varscan2
- COLEC12 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV68373845; called by muse, mutect2, varscan2
- CPED1 | c.2633+2T>A p.X878_splice | Splice Site (SNP) | VAF 65/147 reads (44%) | catalogued as COSV60012926; called by muse, mutect2, varscan2
- CPN2 | c.1568G>A p.W523* | Nonsense Mutation (SNP) | VAF 29/67 reads (43%) | catalogued as COSV60471869; called by muse, mutect2, varscan2
- CRB1 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.585); catalogued as COSV66333518; called by muse, mutect2, varscan2
- CRHR2 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 228/567 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59267847; called by muse, mutect2, varscan2
- CRK | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56032641; called by muse, mutect2, varscan2
- CSPP1 | c.2666C>T p.P889L (on ENST00000676605; = p.P848L on NM_024790.6) | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1357349997, COSV51592486; called by muse, varscan2
- CTIF | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56491525; called by muse, mutect2, varscan2
- CTNNA3 | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); catalogued as COSV65524492; called by muse, mutect2, varscan2
- CTNNA3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV57720821; called by muse, mutect2, varscan2
- CUBN | c.6123T>G p.D2041E | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64726928; called by muse, mutect2, varscan2
- CUBN | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV64719797; called by muse, mutect2, varscan2
- CX3CR1 | c.554A>C p.E185A | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.185); catalogued as COSV64195278; called by muse, mutect2, varscan2
- CYP46A1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.647); catalogued as COSV55896623; called by muse, mutect2, varscan2
- DCDC1 | c.2953G>A p.G985R (on ENST00000597505 / NM_001367979.1; = p.G92R on NM_020869.3) | Missense Mutation (SNP) | VAF 126/323 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60305019; called by muse, mutect2, varscan2
- DLG3 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52087026; called by muse, mutect2, varscan2
- DMXL2 | c.5141C>T p.S1714F | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51855939; called by muse, mutect2, varscan2
- DNAH10 | c.4374G>A p.K1458= (on ENST00000409039; = p.K1397= on NM_207437.3) | Splice Region (SNP) | VAF 36/46 reads (78%) | catalogued as rs554269908, COSV69001276; called by muse, mutect2, varscan2
- DNAH2 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV50020390; called by muse, mutect2, varscan2
- DNAH5 | c.11995C>T p.L3999F | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1223520112, COSV54250078; called by muse, mutect2, varscan2
- DNM3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs904637588, COSV62467013; called by muse, mutect2, varscan2
- DNMBP | c.2969C>T p.S990F | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60632980; called by muse, mutect2, varscan2
- DNTT | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV64523668; called by muse, mutect2, varscan2
- DOCK7 | c.5891A>G p.K1964R (on ENST00000635253 / NM_001367561.1; = p.K1933R on NM_033407.3) | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52020865; called by muse, mutect2, varscan2
- DPYSL5 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV56516140; called by muse, mutect2, varscan2
- DSG2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV55202839; called by muse, mutect2, varscan2
- DSP | c.5788A>G p.T1930A | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65795881; called by muse, mutect2, varscan2
- EDIL3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); catalogued as rs752603385, COSV56901771; called by muse, mutect2, varscan2
- EGFLAM | c.410-1G>A p.X137_splice | Splice Site (SNP) | VAF 107/280 reads (38%) | catalogued as COSV59316862; called by muse, mutect2, varscan2
- EIF4E | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 123/382 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV55189273; called by muse, mutect2, varscan2
- ELMO1 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as COSV60324217; called by muse, mutect2, varscan2
- EMSY | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV58265852; called by muse, mutect2, varscan2
- ENTPD3 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370817654, COSV57196301; called by muse, mutect2, varscan2
- EPHA7 | c.2761G>A p.D921N | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV65191532; called by muse, mutect2, varscan2
- ERBB4 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV53586045; called by muse, mutect2, varscan2
- ERF | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 82/231 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767131852, COSV55894920; called by muse, mutect2, varscan2
- ESM1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67318937; called by muse, mutect2, varscan2
- FAM71B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 83/267 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.225); catalogued as COSV57231169; called by muse, mutect2, varscan2
- FAP | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1408528176, COSV51867429; called by muse, mutect2, varscan2
- FASTKD3 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs750213168, COSV52945372; called by muse, mutect2, varscan2
- FASTKD5 | c.2132C>T p.S711F | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53909552; called by muse, mutect2, varscan2
- FAT3 | c.11572G>A p.D3858N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV53172354; called by muse, mutect2, varscan2
- FBN1 | c.8308C>T p.H2770Y | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs774658482, COSV57330102; called by muse, mutect2, varscan2
- FCGBP | c.12164C>T p.P4055L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as rs1233027438; called by muse, mutect2, varscan2
- FCGBP | c.9575C>T p.A3192V | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs754308006; called by muse, varscan2
- FCN2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.038); catalogued as COSV52478727; called by muse, mutect2, varscan2
- FIGNL1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 61/129 reads (47%) | catalogued as COSV63554072, COSV63554118; called by muse, mutect2, varscan2
- FLT1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV56742622, COSV56743924; called by muse, mutect2, varscan2
- GALNT17 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.877); catalogued as COSV61156162, COSV61190663; called by muse, mutect2
- GFRAL | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV61229588; called by muse, mutect2, varscan2
- GLRA3 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56870010; called by muse, mutect2, varscan2
- GOT2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV55333363; called by muse, mutect2, varscan2
- GPATCH3 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs762217780, COSV64651974; called by muse, mutect2, varscan2
- GPC5 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as COSV65629060; called by muse, mutect2, varscan2
- GPR158 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66282209; called by muse, mutect2, varscan2
- GRAMD2A | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59035223; called by muse, mutect2, varscan2
- GRIN2B | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV74207776, COSV74208280; called by muse, mutect2, varscan2
- GRK1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV59554226; called by muse, mutect2
- GRM4 | c.2728C>T p.H910Y | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.954); catalogued as COSV65219484; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2, varscan2
- H1-7 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1398389521, COSV58601839; called by muse, mutect2, varscan2
- HCAR3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 82/117 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs201704809; called by muse, mutect2, varscan2
- HCFC1 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 62/96 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV60070202; called by muse, mutect2, varscan2
- HRG | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV51648175; called by muse, mutect2, varscan2
- HTR3C | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as rs1484860358, COSV59177304; called by muse, mutect2, varscan2
- IFI44L | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs777441989, COSV60727441; called by muse, mutect2, varscan2
- IGHM | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs782406602; called by muse, mutect2, varscan2
- IGSF9 | c.1934C>T p.P645L (on ENST00000368094 / NM_001135050.2; = p.P629L on NM_020789.4) | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV63642442; called by muse, mutect2, varscan2
- IL32 | c.479C>T p.A160V (on ENST00000396890 / NM_001308078.4; = p.A114V on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.549); catalogued as COSV99145551; called by muse, mutect2, varscan2
- IL7R | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.287); catalogued as COSV57407795, COSV57413989; called by muse, mutect2, varscan2
- INPP5J | c.2143G>A p.E715K (on ENST00000331075 / NM_001284285.2; = p.E347K on NM_001002837.2) | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs1325844838, COSV58515298; called by muse, mutect2, varscan2
- ITGAL | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100776324; called by muse, mutect2, varscan2
- KANSL3 | c.1946C>T p.S649F (on ENST00000666923 / NM_001349262.2; = p.S623F on NM_001115016.3) | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as rs1558673944, COSV62622733; called by muse, mutect2, varscan2
- KCNJ4 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858685; called by muse, mutect2, varscan2
- KCNK18 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57973232; called by muse, mutect2, varscan2
- KCNQ3 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66481536; called by muse, mutect2, varscan2
- KIF25 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63028973; called by muse, mutect2, varscan2
- KLB | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs768972755, COSV57303099; called by muse, mutect2, varscan2
- KLHL14 | c.1444G>A p.G482R | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63835421; called by muse, varscan2
- KRT15 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV54181873; called by muse, mutect2, varscan2
- KRT20 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV51426193; called by muse, mutect2, varscan2
- L1CAM | c.2947C>T p.L983F | Missense Mutation (SNP) | VAF 177/248 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62830109; called by muse, mutect2, varscan2
- LALBA | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV56396526; called by muse, mutect2, varscan2
- LAMA1 | c.7679C>T p.P2560L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs868558649, COSV67544242; called by muse, mutect2, varscan2
- LAMA3 | c.9214G>A p.V3072M (on ENST00000313654 / NM_198129.4; = p.V1463M on NM_000227.6) | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.056); catalogued as COSV52543179; called by muse, mutect2
- LIMCH1 | c.2408G>A p.W803* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV58296346; called by mutect2, varscan2
- LINC02210-CRHR1 | c.243G>A p.E81= | Splice Region (SNP) | VAF 40/129 reads (31%) | catalogued as COSV53285864; called by muse, mutect2, varscan2
- LRP1B | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1423412691, COSV67188779, COSV67197611; called by muse, mutect2, varscan2
- LRP1B | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as rs538520838, COSV67184425; called by muse, mutect2, varscan2
- LRRC4C | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs867956688, COSV53426374, COSV53432590; called by muse, mutect2, varscan2
- LRRIQ3 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100598704, COSV63049804; called by muse, mutect2, varscan2
- LYPD3 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54989644; called by muse, mutect2, varscan2
- MAGEC1 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 97/149 reads (65%) | catalogued as rs1439593642, COSV53581335; called by muse, mutect2, varscan2
- MAP3K9 | c.2116G>A p.G706R (on ENST00000554752 / NM_001284230.1; = p.G720R on NM_033141.4) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV67122823; called by muse, mutect2, varscan2
- MAPK3 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750160678, COSV53774927; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.354); catalogued as rs1375252832, COSV51717858; called by muse, mutect2, varscan2
- MARCHF11 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV60134774; called by muse, mutect2, varscan2
- MASP2 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53571331; called by muse, mutect2, varscan2
- MBD6 | c.2080dup p.Q694Pfs*23 | Frame Shift Ins (INS) | VAF 13/32 reads (41%) | catalogued as rs762648935; called by mutect2, varscan2
- MEGF11 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56561060; called by muse, mutect2, varscan2
- MEGF6 | c.2971C>T p.P991S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV53895775; called by muse, mutect2, varscan2
- MEOX2 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 65/366 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); catalogued as rs772029318, COSV56294611; called by muse, mutect2, varscan2
- MET | c.2387C>A p.S796* | Nonsense Mutation (SNP) | VAF 117/233 reads (50%) | catalogued as COSV59260726, COSV59268873; called by muse, mutect2, varscan2
- MIIP | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.215); catalogued as COSV52428774; called by muse, mutect2, varscan2
- MORC1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51724099, COSV51730937; called by muse, mutect2, varscan2
- MSH5 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs755055223, COSV65211574; called by muse, mutect2, varscan2
- MUC16 | c.15125C>T p.S5042F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs865869833, COSV67477582; called by muse, mutect2, varscan2
- MYH4 | c.4484C>T p.S1495F | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV55113531; called by muse, mutect2, varscan2
- MYH6 | c.5767C>T p.R1923* | Nonsense Mutation (SNP) | VAF 71/209 reads (34%) | catalogued as rs765861895, COSV59306908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1218346694, COSV67972286; called by muse, mutect2, varscan2
- N4BP2 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV54706823; called by muse, mutect2, varscan2
- NAB2 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV55667955; called by muse, mutect2, varscan2
- NECAB1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as rs1299554994, COSV70238009; called by muse, mutect2, varscan2
- NF1 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as CM961025, COSV62197350; called by muse, mutect2, varscan2
- NGF | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772557857, COSV101049373, COSV65686846; called by muse, mutect2, varscan2
- NPR3 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1470296243, COSV54093050; called by muse, mutect2, varscan2
- NSUN5 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV53093727; called by muse, mutect2, varscan2
- NTF4 | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 44/127 reads (35%) | catalogued as COSV56825437; called by muse, mutect2, varscan2
- NUTM2F | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 139/474 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.817); catalogued as COSV53560227; called by muse, mutect2, varscan2
- OAT | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV64348169; called by muse, mutect2, varscan2
- OGFR | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.046); catalogued as COSV51702652; called by muse, mutect2, varscan2
- OLAH | c.736G>A p.E246K (on ENST00000378228 / NM_001039702.3; = p.E299K on NM_018324.3) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1343008369, COSV62252277; called by muse, mutect2, varscan2
- OR10A5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 108/467 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV55053159; called by muse, mutect2, varscan2
- OR11H12 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 35/562 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs756842052; called by muse, mutect2
- OR1B1 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV59172373; called by muse, mutect2, varscan2
- OR1J4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 51/156 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as COSV61590292; called by muse, mutect2, varscan2
- OR2T4 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV63545121; called by muse, mutect2, varscan2
- OR4C6 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.181); catalogued as COSV58606229; called by muse, mutect2, varscan2
- OR4D10 | c.233T>G p.V78G | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV73260203; called by muse, mutect2, varscan2
- OR4K17 | c.61C>T p.Q21* | Nonsense Mutation (SNP) | VAF 131/420 reads (31%) | catalogued as COSV59647607, COSV59649099; called by muse, mutect2, varscan2
- OR51E1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 92/454 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67809512; called by muse, mutect2, varscan2
- OR51G1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as rs142377582, COSV58970739; called by muse, mutect2, varscan2
- OR52M1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 114/220 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100798610, COSV64172790; called by muse, mutect2, varscan2
- OR5AC2 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs562786394, COSV100684561, COSV62279251; called by muse, mutect2, varscan2
- OR5B12 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56906726; called by muse, mutect2, varscan2
- OR5L1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 142/410 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61733151, COSV61735372; called by muse, mutect2, varscan2
- OR8I2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs561919245, COSV56169726, COSV56170425; called by muse, mutect2, varscan2
- OSBPL3 | c.2565C>T p.F855= | Splice Region (SNP) | VAF 105/298 reads (35%) | catalogued as COSV57662370; called by muse, mutect2, varscan2
- OTOGL | c.4359G>A p.M1453I (on ENST00000547103; = p.M1444I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54023478; called by muse, mutect2, varscan2
- PAPPA2 | c.3865C>T p.P1289S | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV62811185; called by muse, mutect2, varscan2
- PAPPA2 | c.4151+1G>A p.X1384_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV62811192; called by muse, mutect2, varscan2
- PCDH18 | c.3397C>T p.R1133C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1386245070, COSV61272057; called by muse, mutect2, varscan2
- PCDH18 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 81/254 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV61266672, COSV61268906; called by muse, mutect2, varscan2
- PCDHA12 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs781855552, COSV56543967; called by muse, mutect2, varscan2
- PCDHB11 | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs782535816, COSV61310815; called by muse, mutect2, varscan2
- PCDHB7 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50801249; called by muse, mutect2, varscan2
- PCDHB8 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as rs782160317, COSV99177245; called by mutect2, varscan2
- PCDHGA5 | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53949497, COSV54029747; called by muse, mutect2, varscan2
- PCSK5 | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762281568, COSV70449275; called by muse, mutect2, varscan2
- PDGFRA | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs267600186, COSV57269077; called by muse, mutect2, varscan2
- PER3 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1328707003, COSV62707846; called by muse, mutect2, varscan2
- PGM2L1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs865915174, COSV53348663; called by muse, mutect2, varscan2
- PIK3C2G | c.1862T>A p.L621H (on ENST00000676171; = p.L580H on NM_004570.5) | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56833043; called by muse, mutect2, varscan2
- PKHD1 | c.11327C>T p.S3776F | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs762661826, COSV64399931; called by muse, mutect2, varscan2
- PLEK2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV53606848; called by muse, mutect2, varscan2
- PLLP | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.369); catalogued as COSV54656753; called by muse, mutect2
- PLTP | c.1141G>T p.G381W | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51944864; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 103/142 reads (73%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV57968748; called by muse, mutect2, varscan2
- POLR3A | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64932084; called by muse, mutect2, varscan2
- POTEF | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs267598869, COSV62544227; called by muse, mutect2, varscan2
- PPFIA3 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53255982, COSV53258770; called by muse, mutect2, varscan2
- PRAMEF6 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 158/1020 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as rs1433844426; called by muse, mutect2
- PRDM1 | c.2174G>A p.R725Q | Missense Mutation (SNP) | VAF 202/692 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs940196192, COSV64846986; called by muse, mutect2, varscan2
- PRIM2 | c.599T>A p.V200D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67310107; called by muse, mutect2, varscan2
- PRKCQ | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.372); catalogued as rs570087260, COSV54117838; called by muse, mutect2, varscan2
- PRKD3 | c.1717G>T p.V573F | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV52218413; called by muse, mutect2, varscan2
- PRLR | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.996); catalogued as COSV51500586; called by muse, mutect2, varscan2
- PSD | c.2414G>A p.G805E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as COSV50060483, COSV99192205; called by muse, mutect2, varscan2
- PSG6 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 241/719 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs865872575, COSV51835669; called by muse, mutect2, varscan2
- PTCHD4 | c.2375G>A p.G792E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV59796611, COSV99045025; called by muse, mutect2, varscan2
- PTGDR | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 134/360 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as rs200050784, COSV60095071; called by muse, mutect2, varscan2
- PTPRC | c.3595C>T p.Q1199* | Nonsense Mutation (SNP) | VAF 61/182 reads (34%) | catalogued as COSV61411735, COSV61420313; called by muse, mutect2, varscan2
- PTPRT | c.3026G>A p.G1009E | Missense Mutation (SNP) | VAF 78/242 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV61964119; called by muse, mutect2, varscan2
- PXDNL | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62498157; called by muse, mutect2, varscan2
- PZP | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV54370223; called by muse, mutect2, varscan2
- RALGDS | c.2459C>T p.T820I | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64429559; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771499244, COSV54588595; called by muse, mutect2, varscan2
- RET | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.628); catalogued as rs1060500755, COSV60708412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFX3 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV56524774; called by muse, mutect2, varscan2
- RGS12 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60681691; called by muse, mutect2, varscan2
- RNASE2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 107/287 reads (37%) | catalogued as COSV58941557; called by muse, mutect2, varscan2
- RP1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55126428; called by muse, varscan2
- RP1 | c.3025G>A p.V1009I | Missense Mutation (SNP) | VAF 158/404 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1244568621, COSV55126440; called by muse, mutect2, varscan2
- RPL10L | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV53561456; called by muse, mutect2, varscan2
- RPS4Y2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56488948; called by muse, mutect2, varscan2
- RREB1 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs754554711, COSV58565317; called by muse, mutect2, varscan2
- RTTN | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 90/285 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490930098, COSV55351975; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV56578219; called by muse, mutect2, varscan2
- SCN5A | c.4916G>A p.G1639E (on ENST00000333535 / NM_198056.3; = p.G1638E on NM_000335.5) | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV61132948, COSV61140371; called by muse, mutect2, varscan2
- SDR42E1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV61095092; called by muse, mutect2, varscan2
- SEMA3D | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs763396779, COSV52393826; called by muse, mutect2, varscan2
- SERPINB13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs376580897; called by muse, mutect2
- SERPINB4 | c.1172A>G p.*391Wext*9 | Nonstop Mutation (SNP) | VAF 133/344 reads (39%) | catalogued as COSV61985905; called by muse, mutect2, varscan2
- SIRPB2 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs756516776, COSV63125333; called by muse, mutect2, varscan2
- SIRPG | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746301292, COSV53810235; called by muse, mutect2, varscan2
- SLC22A6 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64561072, COSV64561144; called by muse, mutect2, varscan2
- SLC25A46 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63506827; called by muse, mutect2, varscan2
- SLC35F3 | c.847C>T p.P283S (on ENST00000366617 / NM_001300845.1; = p.P352S on NM_173508.4) | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs867588567, COSV64018284; called by muse, mutect2, varscan2
- SLC7A13 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV52537159; called by muse, mutect2, varscan2
- SLC8A1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as COSV100247082; called by muse, mutect2, varscan2
- SLIT3 | c.3322T>A p.F1108I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV60632650; called by muse, mutect2, varscan2
- SNRNP48 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs183544051, COSV60940760; called by muse, mutect2, varscan2
- SPAM1 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV56147661; called by muse, mutect2, varscan2
- SPNS2 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs563510360, COSV54604199; called by muse, mutect2, varscan2
- SPOCK3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV62734042, COSV62741008; called by muse, mutect2, varscan2
- SPRR1B | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61067429, COSV61068080; called by muse, mutect2, varscan2
- SPTAN1 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs202099793, COSV63989774; called by muse, mutect2, varscan2
- STXBP5L | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1347085003, COSV56514279, COSV56521455; called by muse, mutect2, varscan2
- STYXL1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 215/847 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs1554576307, COSV50392516; called by muse, mutect2, varscan2
- SUPT5H | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 159/500 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV63242067; called by muse, mutect2, varscan2
- TBX10 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 111/311 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56876620; called by muse, mutect2, varscan2
- TCP1 | c.173G>A p.G58D | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58460370; called by muse, mutect2, varscan2
- TDRD6 | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV60178521; called by muse, mutect2
- TFG | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs777143620, COSV53749299, COSV53750174; called by muse, mutect2, varscan2
- TGM4 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs774638487, COSV56093317; called by muse, mutect2, varscan2
- THSD7B | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV55736170, COSV99742264; called by muse, mutect2
- TNFSF14 | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV55591734; called by muse, mutect2, varscan2
- TNKS1BP1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64100422; called by muse, mutect2, varscan2
- TNS1 | c.3905G>A p.R1302H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs533811485, COSV50765331; called by muse, mutect2, varscan2
- TNS3 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV60799154; called by muse, mutect2, varscan2
- TRIM56 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 87/339 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60161361; called by muse, mutect2, varscan2
- TRIML2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs1373521206, COSV58717106, COSV58719474; called by muse, mutect2, varscan2
- TRPV5 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54689720; called by muse, mutect2, varscan2
- TSHZ1 | c.2090C>T p.A697V (on ENST00000580243 / NM_001308210.2; = p.A652V on NM_005786.6) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59016795; called by muse, mutect2, varscan2
- TTN | c.58462G>A p.E19488K (on ENST00000591111; = p.E12064K on NM_003319.4) | Missense Mutation (SNP) | VAF 35/83 reads (42%) | PolyPhen possibly damaging (0.453); catalogued as COSV60340313; called by muse, mutect2, varscan2
- TTN | c.14135G>A p.R4712Q (on ENST00000591111; = p.R3785Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | PolyPhen benign (0.007); catalogued as rs200792058; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- TXNDC11 | c.2058C>A p.F686L (on ENST00000356957 / NM_001303447.2; = p.F659L on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV51603090; called by muse, mutect2, varscan2
- UBE4A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52806921; called by muse, mutect2, varscan2
- UBQLNL | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV66494565; called by muse, mutect2, varscan2
- UNC5A | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV52844423; called by muse, mutect2, varscan2
- USH1C | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs754055631, COSV50014997; called by muse, mutect2, varscan2
- VPS8 | c.3422C>T p.A1141V (on ENST00000625842 / NM_001349294.1; = p.A1139V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV54996424; called by muse, mutect2, varscan2
- VRTN | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as COSV56443587; called by muse, mutect2, varscan2
- WNK2 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52960073; called by muse, mutect2, varscan2
- WNK2 | c.5134C>T p.Q1712* (on ENST00000297954 / NM_001282394.1; = p.Q1675* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 103/284 reads (36%) | catalogued as COSV52960117; called by muse, mutect2, varscan2
- WNT10B | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 112/320 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV56406403, COSV56406445; called by muse, mutect2, varscan2
- XKR3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs762843866, COSV58884790; called by muse, mutect2, varscan2
- ZCCHC2 | c.2401C>T p.P801S | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as COSV54041024; called by muse, mutect2, varscan2
- ZDBF2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV65629892; called by muse, mutect2, varscan2
- ZMIZ1 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.899); catalogued as COSV100566444; called by muse, mutect2, varscan2
- ZMIZ1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs766670423, COSV100566445; called by muse, mutect2, varscan2
- ZMIZ2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54810920; called by muse, mutect2, varscan2
- ZNF232 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV51504868; called by muse, mutect2, varscan2
- ZNF350 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54710586; called by muse, mutect2, varscan2
- ZNF615 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV65034868; called by muse, mutect2, varscan2
- ZNF677 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61721500; called by muse, mutect2, varscan2
- ZSWIM5 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 57/145 reads (39%) | catalogued as COSV62736860; called by muse, mutect2, varscan2
- ZWILCH | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57183054; called by muse, mutect2, varscan2
- ADGRV1 | c.10331del p.N3444Tfs*24 | Frame Shift Del (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- IGHM | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- NUTM2D | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- PLBD2 | c.468del p.S157Afs*7 | Frame Shift Del (DEL) | VAF 197/370 reads (53%) | called by mutect2, pindel, varscan2
- SCUBE3 | c.2675_2679dup p.L894Gfs*33 | Frame Shift Ins (INS) | VAF 252/641 reads (39%) | called by mutect2, pindel, varscan2
- TMEM185A | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADAMTS6 | c.2004G>A p.A668= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as rs375845443, COSV66864585; called by muse, mutect2, varscan2
- ADGRE1 | c.1851C>T p.L617= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs770567929, COSV51680864, COSV99164980; called by muse, mutect2, varscan2
- ADGRL3 | c.912G>A p.R304= (on ENST00000506720 / NM_001322402.2; = p.R236= on NM_015236.6) | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV72273261; called by muse, mutect2, varscan2
- AKR1C2 | c.489C>T p.I163= | Silent (SNP) | VAF 66/195 reads (34%) | catalogued as rs139670873, COSV66333147; called by muse, mutect2, varscan2
- ARHGEF11 | c.2076C>T p.L692= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV59358527; called by muse, mutect2, varscan2
- ASTN1 | c.3510G>A p.G1170= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV62506101; called by muse, mutect2, varscan2
- BEND4 | c.834C>T p.D278= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1221194480, COSV101549789; called by muse, mutect2, varscan2
- BSN | c.8019C>T p.S2673= | Silent (SNP) | VAF 39/144 reads (27%) | catalogued as rs140023119, COSV56527115; called by muse, mutect2, varscan2
- C2orf78 | c.1950C>T p.F650= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV68516704, COSV68519366; called by muse, mutect2, varscan2
- C9orf152 | c.306G>A p.L102= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV68763141; called by muse, mutect2, varscan2
- CA10 | c.501G>A p.T167= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as rs769181729, COSV53362898, COSV99564932; called by muse, mutect2, varscan2
- CA4 | c.231G>A p.K77= | Silent (SNP) | VAF 73/197 reads (37%) | catalogued as COSV56282722; called by muse, mutect2, varscan2
- CACNA1A | c.3729C>T p.I1243= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV64212135; called by muse, mutect2, varscan2
- CAPN3 | c.795C>T p.S265= | Silent (SNP) | VAF 95/273 reads (35%) | catalogued as CD164404, COSV58826202; called by muse, mutect2, varscan2
- CAPN6 | c.489G>A p.L163= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as COSV60697162; called by muse, mutect2, varscan2
- CAPN9 | c.1158G>A p.E386= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV55239537; called by muse, mutect2, varscan2
- CCDC54 | c.786C>T p.F262= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as rs952135988, COSV53759841; called by muse, mutect2, varscan2
- CD33 | c.1053C>T p.S351= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99220702; called by muse, mutect2, varscan2
- CDH13 | c.903C>T p.I301= | Silent (SNP) | VAF 69/168 reads (41%) | catalogued as rs377468582; called by muse, mutect2, varscan2
- CEP104 | c.2682C>T p.A894= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs757805931, COSV65519658; called by muse, mutect2, varscan2
- CFAP43 | c.1992C>T p.I664= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV53381166; called by muse, mutect2, varscan2
- CFAP70 | c.2475A>T p.L825= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV60286799; called by muse, mutect2, varscan2
- CFHR1 | c.264C>T p.F88= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV57629125; called by muse, mutect2, varscan2
- CHCHD3 | c.594C>T p.T198= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV52783121; called by muse, mutect2, varscan2
- CLASP1 | c.354C>T p.I118= | Silent (SNP) | VAF 162/420 reads (39%) | catalogued as COSV55339980; called by muse, mutect2, varscan2
- CLIC5 | c.607C>T p.L203= (on ENST00000185206 / NM_001370649.1; = p.L44= on NM_016929.5) | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as COSV51765417; called by muse, mutect2, varscan2
- CNR1 | c.156C>T p.S52= | Silent (SNP) | VAF 33/91 reads (36%) | catalogued as COSV100759313; called by muse, mutect2, varscan2
- COL4A5 | c.1503C>T p.L501= | Silent (SNP) | VAF 57/89 reads (64%) | catalogued as COSV60371801; called by muse, mutect2, varscan2
- COL5A3 | c.5190G>A p.T1730= | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as rs1206800800, COSV53407015; called by muse, mutect2, varscan2
- COL6A3 | c.5565G>A p.Q1855= | Silent (SNP) | VAF 112/300 reads (37%) | catalogued as COSV55109095; called by muse, mutect2, varscan2
- CRYBG1 | c.3147A>C p.T1049= | Silent (SNP) | VAF 53/170 reads (31%) | catalogued as COSV64814532; called by muse, mutect2, varscan2
- CYP2C18 | c.1284C>T p.F428= | Silent (SNP) | VAF 57/197 reads (29%) | catalogued as COSV53674753; called by muse, mutect2, varscan2
- CYP4F11 | c.1107G>A p.E369= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV56129485; called by muse, mutect2, varscan2
- DAGLA | c.2484C>T p.P828= | Silent (SNP) | VAF 239/822 reads (29%) | catalogued as rs373810848; called by muse, mutect2, varscan2
- DEUP1 | c.1101G>A p.R367= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV53216574; called by muse, mutect2, varscan2
- DNAH1 | c.462C>T p.I154= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs759571672, COSV70236085; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUSP29 | c.555G>A p.P185= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as rs762330745, COSV58300737; called by muse, mutect2, varscan2
- DYNC1H1 | c.9927C>T p.S3309= | Silent (SNP) | VAF 133/408 reads (33%) | catalogued as COSV64142277; called by muse, mutect2, varscan2
- ECT2L | c.1989C>T p.F663= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV62885256, COSV62887149; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1434C>T p.I478= (on ENST00000361735 / NM_015935.5; = p.I392= on NM_014955.3) | Silent (SNP) | VAF 64/200 reads (32%) | catalogued as rs1476750167, COSV62283536; called by muse, mutect2, varscan2
- EGFLAM | c.1011C>T p.A337= | Silent (SNP) | VAF 56/177 reads (32%) | catalogued as COSV59316883, COSV59319706; called by muse, mutect2, varscan2
- EPHA6 | c.870C>T p.A290= | Silent (SNP) | VAF 202/489 reads (41%) | catalogued as rs1433877378, COSV67593414; called by muse, mutect2, varscan2
- ESRRB | c.759C>T p.V253= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as COSV55058116; called by muse, mutect2, varscan2
- EXD3 | c.730C>T p.L244= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV59813469; called by muse, mutect2, varscan2
- FABP6 | c.111C>T p.I37= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as rs762811726, COSV67436976; called by muse, mutect2, varscan2
- FAM135B | c.144C>T p.I48= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs751821996, COSV50539735; called by muse, mutect2, varscan2
- FAT3 | c.1497G>A p.K499= | Silent (SNP) | VAF 41/57 reads (72%) | catalogued as COSV53172329; called by muse, mutect2, varscan2
- FBXO39 | c.576G>A p.E192= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV58623086; called by muse, mutect2, varscan2
- FERMT2 | c.1329C>T p.L443= | Silent (SNP) | VAF 105/291 reads (36%) | catalogued as rs1373507599, COSV58406008, COSV58409360; called by muse, mutect2, varscan2
- FMNL2 | c.2742G>A p.K914= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1014300294, COSV56504363; called by muse, mutect2, varscan2
- FRMPD3 | c.2664C>T p.G888= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs747060737, COSV52189187; called by muse, mutect2, varscan2
- GIMAP6 | c.306C>T p.P102= | Silent (SNP) | VAF 126/238 reads (53%) | catalogued as COSV61034753; called by muse, mutect2, varscan2
- GINS2 | c.327G>A p.K109= | Silent (SNP) | VAF 76/199 reads (38%) | catalogued as COSV53675939; called by muse, mutect2, varscan2
- GLI3 | c.948C>T p.S316= | Silent (SNP) | VAF 119/224 reads (53%) | catalogued as rs1458216501, COSV67894745; called by muse, mutect2, varscan2
- GPR137 | c.1050C>T p.A350= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as COSV57403901; called by muse, mutect2, varscan2
- GRIN2B | c.1704C>T p.I568= | Silent (SNP) | VAF 63/193 reads (33%) | catalogued as rs202102041; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAS3 | c.312C>T p.C104= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV54709259; called by muse, mutect2, varscan2
- HAUS5 | c.867C>T p.S289= | Silent (SNP) | VAF 58/162 reads (36%) | catalogued as rs1306772399, COSV52549813; called by muse, mutect2, varscan2
- HDAC9 | c.450C>T p.F150= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV67784929; called by muse, mutect2
- IFT140 | c.1791C>T p.S597= | Silent (SNP) | VAF 77/210 reads (37%) | catalogued as COSV68497907; called by muse, mutect2, varscan2
- IGHV2-26 | c.321C>T p.D107= | Silent (SNP) | VAF 126/379 reads (33%) | called by muse, mutect2, varscan2
- IL17RE | c.561C>T p.A187= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs1213709206, COSV55970802; called by muse, mutect2, varscan2
- IQSEC3 | c.1057C>T p.L353= (on ENST00000538872 / NM_001170738.2; = p.L50= on NM_015232.1) | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV58287105; called by muse, mutect2, varscan2
- ITGAD | c.2958C>T p.A986= | Silent (SNP) | VAF 58/176 reads (33%) | catalogued as COSV54932707, COSV54932740; called by muse, mutect2, varscan2
- ITGAL | c.285G>A p.L95= | Silent (SNP) | VAF 53/196 reads (27%) | catalogued as COSV100776323; called by muse, mutect2, varscan2
- ITPR1 | c.5679G>A p.R1893= (on ENST00000354582; = p.R1838= on NM_002222.7) | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV57003318; called by muse, mutect2, varscan2
- JAKMIP1 | c.1854C>T p.L618= | Silent (SNP) | VAF 73/138 reads (53%) | catalogued as COSV99288421; called by muse, mutect2, varscan2
- KCNH5 | c.2304G>A p.V768= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV59772407; called by muse, mutect2, varscan2
- KCNJ4 | c.465C>T p.V155= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV57858693; called by muse, varscan2
- KCNJ4 | c.364C>T p.L122= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as COSV57858703; called by muse, varscan2
- KCNN3 | c.1005C>T p.I335= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs754028439, COSV55226805; called by muse, mutect2, varscan2
- KIAA0930 | c.1053C>T p.S351= (on ENST00000336156 / NM_001009880.2; = p.S356= on NM_015264.2) | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as rs1427175630, COSV52665699; called by muse, mutect2, varscan2
- KIF27 | c.2884C>T p.L962= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV52831096; called by muse, mutect2, varscan2
- KMT2D | c.3924C>T p.F1308= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV56485172; called by muse, mutect2
- KRT16 | c.501C>T p.Y167= | Silent (SNP) | VAF 129/399 reads (32%) | catalogued as COSV56966831, COSV56969708; called by muse, mutect2, varscan2
- KRT35 | c.1224C>T p.L408= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV55844532; called by muse, mutect2, varscan2
- KSR2 | c.486C>T p.S162= | Silent (SNP) | VAF 187/254 reads (74%) | catalogued as COSV60394506; called by muse, mutect2, varscan2
- LILRB5 | c.1408C>T p.L470= (on ENST00000449561 / NM_001081442.3; = p.L469= on NM_006840.5) | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV60254460; called by muse, mutect2, varscan2
- LRFN2 | c.696C>T p.A232= | Silent (SNP) | VAF 46/177 reads (26%) | catalogued as rs996523141, COSV57834480; called by muse, mutect2, varscan2
- LRRIQ4 | c.477G>A p.K159= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as COSV61620164; called by muse, mutect2, varscan2
- LTB4R2 | c.171C>T p.F57= (on ENST00000528054; = p.F26= on NM_019839.5) | Silent (SNP) | VAF 63/189 reads (33%) | catalogued as COSV51868091; called by muse, mutect2, varscan2
- MAP3K19 | c.3417C>T p.F1139= | Silent (SNP) | VAF 90/240 reads (38%) | catalogued as COSV59638256; called by muse, mutect2, varscan2
- MAST1 | c.2604G>A p.S868= | Silent (SNP) | VAF 118/367 reads (32%) | catalogued as rs528017416, COSV52247474; called by muse, mutect2, varscan2
- MED25 | c.1347C>T p.I449= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as COSV57207272; called by muse, mutect2, varscan2
- MET | c.660G>A p.K220= | Silent (SNP) | VAF 117/436 reads (27%) | catalogued as COSV59268861; called by muse, mutect2, varscan2
- MIA2 | c.1659A>G p.K553= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as rs142402603; called by muse, mutect2
- MTERF3 | c.849C>T p.L283= | Silent (SNP) | VAF 56/155 reads (36%) | catalogued as COSV54634500; called by muse, mutect2, varscan2
- MTNR1A | c.858C>T p.F286= | Silent (SNP) | VAF 93/241 reads (39%) | catalogued as COSV56157198; called by muse, mutect2, varscan2
- MUC16 | c.8502G>A p.T2834= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs908281742, COSV67445873; called by muse, mutect2, varscan2
- MXRA5 | c.1569G>A p.A523= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as rs144210017, COSV54249997, COSV99476713; called by muse, mutect2, varscan2
- MYO10 | c.5190C>T p.I1730= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV57029832; called by muse, mutect2, varscan2
- MYO18B | c.2676G>A p.E892= | Silent (SNP) | VAF 168/536 reads (31%) | catalogued as COSV59148190; called by muse, mutect2
- MYO7B | c.69C>T p.A23= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV67344884; called by muse, mutect2
- NCAM1 | c.1500G>A p.L500= (on ENST00000316851 / NM_181351.5; = p.L490= on NM_000615.7) | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as COSV57524503; called by muse, mutect2, varscan2
- NGF | c.321C>T p.V107= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs202005277; called by muse, mutect2, varscan2
- NLRP4 | c.72G>A p.R24= | Silent (SNP) | VAF 81/251 reads (32%) | catalogued as rs1357192821, COSV56715473; called by muse, mutect2, varscan2
- NOSTRIN | c.123G>A p.L41= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV58324117; called by muse, mutect2, varscan2
- NRK | c.2769C>T p.L923= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as COSV54606520; called by muse, mutect2, varscan2
- NXPE3 | c.213C>T p.S71= | Silent (SNP) | VAF 112/312 reads (36%) | catalogued as rs1373554655, COSV56292219; called by muse, mutect2, varscan2
- OR1L3 | c.312C>T p.F104= | Silent (SNP) | VAF 110/304 reads (36%) | catalogued as rs1177707740, COSV59169357; called by muse, mutect2, varscan2
- OR1S2 | c.333C>T p.I111= | Silent (SNP) | VAF 85/290 reads (29%) | catalogued as rs1565105094, COSV56920706; called by muse, mutect2, varscan2
- OR2D2 | c.426C>T p.V142= | Silent (SNP) | VAF 116/231 reads (50%) | catalogued as rs777967219, COSV55058230; called by muse, mutect2, varscan2
- OR4C13 | c.93C>T p.V31= | Silent (SNP) | VAF 245/482 reads (51%) | catalogued as COSV73648925; called by muse, mutect2, varscan2
- OR4F15 | c.664C>T p.L222= | Silent (SNP) | VAF 84/251 reads (33%) | catalogued as COSV59968445, COSV59970324; called by muse, mutect2, varscan2
- OR4K17 | c.810C>T p.F270= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV59647360; called by muse, mutect2, varscan2
- OR4X2 | c.162C>T p.F54= | Silent (SNP) | VAF 74/294 reads (25%) | catalogued as rs1318767507, COSV56582525; called by muse, mutect2, varscan2
- OTOF | c.5871C>T p.F1957= (on ENST00000272371 / NM_194248.3; = p.F1190= on NM_004802.4) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV55519004; called by muse, mutect2, varscan2
- PCDHA12 | c.1263T>C p.Y421= | Silent (SNP) | VAF 160/542 reads (30%) | catalogued as rs782576636, COSV56543976; called by muse, mutect2, varscan2
- PCDHB4 | c.1917C>T p.L639= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as COSV52026899; called by muse, mutect2, varscan2
- PCLO | c.10485G>A p.G3495= | Silent (SNP) | VAF 49/209 reads (23%) | catalogued as rs1211934291, COSV61665213; called by muse, mutect2, varscan2
- PDE11A | c.1023G>A p.A341= | Silent (SNP) | VAF 70/205 reads (34%) | catalogued as rs373110295, COSV53700020; called by muse, mutect2, varscan2
- PHETA2 | c.96C>T p.T32= | Silent (SNP) | VAF 105/287 reads (37%) | catalogued as rs1279561447, COSV58791483; called by muse, mutect2, varscan2
- PI4KA | c.2622C>T p.P874= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs367828826; called by muse, mutect2, varscan2
- PITRM1 | c.3009C>T p.A1003= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs749521401, COSV56525746; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>A p.G2768= | Silent (SNP) | VAF 75/187 reads (40%) | catalogued as rs747019693, COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PKP2 | c.1959G>A p.R653= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV50731234; called by muse, mutect2, varscan2
- PLD4 | c.705G>A p.R235= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV66915728; called by muse, mutect2, varscan2
- PLG | c.2079C>T p.V693= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as rs1562381366, COSV57516387; called by muse, mutect2, varscan2
- PLXDC1 | c.1359C>T p.S453= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV59553869; called by muse, mutect2, varscan2
- PROM2 | c.1081C>T p.L361= | Silent (SNP) | VAF 52/167 reads (31%) | catalogued as COSV58300791; called by muse, mutect2, varscan2
- PSG8 | c.780C>T p.F260= | Silent (SNP) | VAF 181/581 reads (31%) | catalogued as COSV60615752; called by muse, mutect2, varscan2
- PTCHD4 | c.1245G>A p.L415= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV59796620; called by muse, mutect2, varscan2
- PTK2B | c.477G>A p.R159= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV57765814; called by muse, mutect2, varscan2
- PTPRC | c.3468G>A p.G1156= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV61416958; called by muse, mutect2, varscan2
- PTPRK | c.3864G>A p.E1288= (on ENST00000368215 / NM_001291984.2; = p.E1289= on NM_002844.4) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as rs199704388, COSV63906910; called by muse, mutect2, varscan2
- RADX | c.723C>T p.I241= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV100998828, COSV65320061; called by muse, mutect2, varscan2
- RHBDL1 | c.1053C>A p.S351= (on ENST00000219551 / NM_001318733.2; = p.S286= on NM_001278720.2) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53486781; called by muse, mutect2, varscan2
- RIMS2 | c.4371C>T p.I1457= (on ENST00000666250 / NM_001348490.2; = p.I1028= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV51656680; called by muse, mutect2, varscan2
- RIN2 | c.1065C>T p.S355= (on ENST00000255006 / NM_001242581.1; = p.S306= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as rs774266496, COSV54794155; called by muse, mutect2, varscan2
- RP1 | c.309C>T p.S103= | Silent (SNP) | VAF 82/226 reads (36%) | catalogued as COSV55126406; called by muse, varscan2
- SAMD7 | c.54C>T p.I18= | Silent (SNP) | VAF 77/180 reads (43%) | catalogued as rs151002058; called by muse, mutect2, varscan2
- SCLT1 | c.909C>T p.T303= | Silent (SNP) | VAF 61/187 reads (33%) | catalogued as rs533835730, COSV55410704; called by muse, mutect2, varscan2
- SDK2 | c.4551C>T p.S1517= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs757461777, COSV66191757; called by muse, mutect2
- SEMA3D | c.2241C>T p.G747= | Silent (SNP) | VAF 96/205 reads (47%) | catalogued as COSV52404274, COSV99406906; called by muse, mutect2, varscan2
- SEMA6C | c.2083C>T p.L695= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59007709; called by muse, mutect2
- SERPINB4 | c.324C>T p.F108= | Silent (SNP) | VAF 105/317 reads (33%) | catalogued as rs370255131; called by muse, mutect2, varscan2
- SGSM1 | c.3315G>A p.L1105= (on ENST00000400359 / NM_001039948.4; = p.L1044= on NM_133454.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV68509843; called by muse, mutect2, varscan2
- SH3KBP1 | c.264G>A p.T88= | Silent (SNP) | VAF 80/109 reads (73%) | catalogued as rs375522869, COSV101114449, COSV65644580; called by muse, mutect2, varscan2
- SH3RF1 | c.2403C>T p.S801= | Silent (SNP) | VAF 88/238 reads (37%) | catalogued as COSV52925245; called by muse, mutect2, varscan2
- SHROOM1 | c.1005C>A p.P335= | Silent (SNP) | VAF 101/275 reads (37%) | catalogued as COSV60582531; called by muse, mutect2, varscan2
- SIGLEC1 | c.3678G>A p.L1226= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV52472153; called by muse, mutect2, varscan2
- SIPA1L3 | c.1992G>A p.K664= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs899632489, COSV55924010; called by muse, mutect2, varscan2
- SLC22A14 | c.564C>T p.I188= | Silent (SNP) | VAF 102/293 reads (35%) | catalogued as COSV56199388; called by muse, mutect2, varscan2
- SLC35F3 | c.591C>T p.I197= (on ENST00000366617 / NM_001300845.1; = p.I266= on NM_173508.4) | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV64021009; called by muse, mutect2, varscan2
- SLC39A8 | c.399C>T p.F133= | Silent (SNP) | VAF 77/263 reads (29%) | catalogued as COSV63224139; called by muse, mutect2
- SLC52A3 | c.1143G>A p.A381= | Silent (SNP) | VAF 34/100 reads (34%) | catalogued as rs756997756, COSV54079312; called by muse, mutect2, varscan2
- SLC6A12 | c.1095C>T p.I365= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs771756771, COSV62885102; called by muse, mutect2, varscan2
- SLC8A1 | c.2121A>G p.G707= | Silent (SNP) | VAF 89/261 reads (34%) | catalogued as COSV100247083; called by muse, mutect2, varscan2
- SLC9A2 | c.447C>T p.I149= | Silent (SNP) | VAF 183/530 reads (35%) | catalogued as rs143241362, COSV99296958; called by muse, mutect2, varscan2
- SLCO6A1 | c.72C>T p.A24= | Silent (SNP) | VAF 151/422 reads (36%) | catalogued as rs774476039, COSV65810707; called by muse, mutect2, varscan2
- SLIT3 | c.870C>T p.I290= | Silent (SNP) | VAF 71/259 reads (27%) | catalogued as rs372775604, COSV100270931; called by muse, mutect2, varscan2
- SOWAHB | c.2088G>A p.R696= | Silent (SNP) | VAF 223/666 reads (33%) | catalogued as rs1451320082, COSV57555492; called by muse, mutect2, varscan2
- SPTA1 | c.6684C>T p.I2228= | Silent (SNP) | VAF 142/433 reads (33%) | catalogued as COSV63759178; called by muse, mutect2, varscan2
- SRPX | c.711C>T p.I237= | Silent (SNP) | VAF 73/96 reads (76%) | catalogued as COSV59441397; called by muse, mutect2, varscan2
- ST18 | c.237G>A p.E79= | Silent (SNP) | VAF 146/414 reads (35%) | catalogued as COSV52508961; called by muse, mutect2, varscan2
- STAC2 | c.1080A>G p.Q360= | Silent (SNP) | VAF 50/166 reads (30%) | catalogued as rs1253057608, COSV61066794; called by muse, mutect2, varscan2
- SUZ12 | c.681C>T p.F227= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV59503423; called by muse, mutect2, varscan2
- SVOPL | c.795A>G p.K265= (on ENST00000419765; = p.K113= on NM_174959.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/152 reads (49%) | catalogued as COSV55995304; called by muse, mutect2, varscan2
- TANGO6 | c.2817C>T p.V939= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV55772706; called by muse, mutect2, varscan2
- TDRD5 | c.2169C>T p.I723= | Silent (SNP) | VAF 66/191 reads (35%) | catalogued as COSV54250167; called by muse, mutect2, varscan2
- TERT | c.3096C>T p.F1032= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs757204201, COSV57228603; called by muse, mutect2, varscan2
- TMEM132D | c.2640C>T p.T880= | Silent (SNP) | VAF 72/111 reads (65%) | catalogued as COSV67162373; called by muse, mutect2, varscan2
- TMEM168 | c.1038C>T p.S346= | Silent (SNP) | VAF 260/516 reads (50%) | catalogued as COSV57182458; called by muse, mutect2, varscan2
- TMEM94 | c.1158C>T p.F386= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV58595746; called by muse, mutect2, varscan2
- TNXB | c.8040C>T p.V2680= (on ENST00000647633; = p.V2433= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 118/246 reads (48%) | catalogued as COSV64478257, COSV64488621; called by muse, mutect2, varscan2
- TRAV18 | c.112C>T p.L38= | Silent (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- TRAV6 | c.348C>T p.I116= | Silent (SNP) | VAF 162/476 reads (34%) | called by muse, mutect2, varscan2
- TRBV4-2 | c.282C>T p.F94= | Silent (SNP) | VAF 267/1237 reads (22%) | called by muse, mutect2, varscan2
- TRIM42 | c.1371C>T p.I457= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV53886871; called by muse, mutect2, varscan2
- TTC13 | c.772C>T p.L258= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as COSV64169988; called by muse, mutect2, varscan2
- TTI1 | c.867C>T p.I289= | Silent (SNP) | VAF 124/353 reads (35%) | catalogued as COSV65062037, COSV65063489; called by muse, mutect2, varscan2
- TXNL1 | c.579T>C p.Y193= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99469825; called by muse, mutect2, varscan2
- UGT2B28 | c.270C>T p.I90= | Silent (SNP) | VAF 100/285 reads (35%) | catalogued as COSV59432715; called by muse, mutect2, varscan2
- USP20 | c.2394C>T p.I798= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs748458000, COSV59618908; called by muse, mutect2, varscan2
- WDR3 | c.1161C>T p.N387= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV62525207; called by muse, mutect2, varscan2
- ZBTB38 | c.2823G>A p.K941= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV58544139; called by muse, mutect2, varscan2
- ZC3HAV1L | c.588C>T p.S196= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV51965130; called by muse, mutect2, varscan2
- ZFYVE19 | c.486C>T p.P162= (on ENST00000355341 / NM_001077268.2; = p.P152= on NM_032850.5) | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as COSV54542213; called by muse, mutect2, varscan2
- ZKSCAN1 | c.318C>A p.S106= | Silent (SNP) | VAF 66/243 reads (27%) | catalogued as COSV60875681; called by muse, mutect2, varscan2
- ZNF165 | c.1410C>T p.N470= | Silent (SNP) | VAF 31/134 reads (23%) | catalogued as rs368569898; called by muse, mutect2, varscan2
- ZNF365 | c.471C>T p.F157= | Silent (SNP) | VAF 60/188 reads (32%) | catalogued as rs372546111; called by muse, mutect2, varscan2
- ZNF385B | c.270G>A p.Q90= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV69807458; called by muse, mutect2, varscan2
- ZNF488 | c.348G>A p.Q116= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852380 G>A | 3'Flank (SNP) | VAF 18/20 reads (90%) | called by muse, mutect2
- CFAP74 | c.4654-257G>A | Intron (SNP) | VAF 40/115 reads (35%) | catalogued as COSV60587961; called by muse, mutect2, varscan2
- COMMD9 | chr11:36271681 A>C | 3'Flank (SNP) | VAF 8/48 reads (17%) | catalogued as rs775456608; called by muse, varscan2
- DOCK3 | c.163-12546C>T | Intron (SNP) | VAF 46/130 reads (35%) | catalogued as COSV56502089; called by muse, mutect2, varscan2
- HMGB1P1 | n.11G>A | RNA (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
- MIR1297 | n.14G>A | RNA (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- NRXN3 | c.989-7399C>T | Intron (SNP) | VAF 69/210 reads (33%) | catalogued as rs1568459959; called by muse, mutect2, varscan2
- RCC1 | c.-261-582G>A | Intron (SNP) | VAF 61/209 reads (29%) | catalogued as COSV63120939; called by muse, mutect2, varscan2
- RCC1 | c.-261-581G>A | Intron (SNP) | VAF 60/208 reads (29%) | catalogued as rs1370752775, COSV100775660; called by muse, mutect2, varscan2
- RMDN2 | c.453-22074C>T | Intron (SNP) | VAF 67/221 reads (30%) | catalogued as COSV52222144; called by muse, mutect2, varscan2
- TEX2 | c.2177-18C>T | Intron (SNP) | VAF 39/109 reads (36%) | catalogued as COSV51985489; called by muse, mutect2, varscan2
- TUBB7P | n.958C>T | RNA (SNP) | VAF 88/283 reads (31%) | catalogued as rs781898441; called by muse, mutect2, varscan2
- ZNF665 | c.-53-9153G>T | Intron (SNP) | VAF 112/346 reads (32%) | catalogued as COSV67213245, COSV67214821; called by muse, mutect2, varscan2
